Somatic mutation profile of tumor specimen TCGA-14-0786-01B (aliquot TCGA-14-0786-01B-01D-1492-08) from TCGA case TCGA-14-0786, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.9 years (18,592 days).
Specimen TCGA-14-0786-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 907be98d-dcf1-4394-8c27-22d465c09f61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0786-10A (Blood Derived Normal), aliquot TCGA-14-0786-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2df12676-9f01-4c6f-ab71-bc0361ded3f9

The open-access MAF lists 37 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Frame Shift Del 1, RNA 1, Intron 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 3857/4604 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1044020461, COSV54027813; called by muse, mutect2, varscan2
- ABO | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs899999370, COSV71743502; called by muse, mutect2, varscan2
- C3orf20 | c.2356T>A p.F786I | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV53784489; called by muse, mutect2, varscan2
- CAD | c.6424C>A p.L2142I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV53025671, COSV53028068; called by muse, mutect2, varscan2
- EEF1A1 | c.188T>G p.L63R | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV58549355; called by muse, mutect2, varscan2
- FHDC1 | c.3392G>A p.R1131Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV52599115; called by muse, mutect2, varscan2
- ITIH5 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 72/87 reads (83%) | SIFT tolerated (0.54); PolyPhen benign (0.157); catalogued as rs747244720, COSV56898161; called by muse, mutect2, varscan2
- KCND1 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs782465232, COSV54413563; called by muse, mutect2, varscan2
- KCNQ1 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs771239108, COSV50105158; called by muse, mutect2, varscan2
- KRTAP19-2 | c.33C>A p.S11R | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV61854653; called by muse, mutect2, varscan2
- LDHAL6A | c.388C>G p.H130D | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55007570; called by muse, mutect2
- MAGEC2 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 222/574 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as COSV55998923; called by muse, mutect2, varscan2
- NLGN4X | c.2153C>A p.T718K | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.045); catalogued as COSV52013600; called by muse, mutect2, varscan2
- PPIG | c.1332A>C p.K444N | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV53642530; called by muse, mutect2, varscan2
- PRKD3 | c.1399C>G p.R467G | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1449554884, COSV52212563; called by muse, mutect2, varscan2
- RYR2 | c.4753C>T p.R1585C | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs528206995, COSV63679348; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC30A8 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs775084835, COSV69969834; called by muse, mutect2, varscan2
- SLIT2 | c.1964C>A p.S655Y | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV56568708; called by muse, mutect2, varscan2
- SSX3 | c.331-1G>A p.X111_splice | Splice Site (SNP) | VAF 248/588 reads (42%) | catalogued as COSV53643862; called by muse, mutect2, varscan2
- ST6GAL2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 28/76 reads (37%) | PolyPhen benign (0); catalogued as rs758806051, COSV64527663; called by muse, mutect2, varscan2
- TONSL | c.1942G>A p.D648N | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV101340324, COSV68048125; called by muse, mutect2, varscan2
- ZDHHC1 | c.1114T>A p.S372T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52083749; called by muse, mutect2, varscan2
- ALPK1 | c.2397del p.L800* | Frame Shift Del (DEL) | VAF 43/115 reads (37%) | called by mutect2, pindel, varscan2
- NTF3 | c.84A>T p.E28D | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.084); called by muse, mutect2
- ANO5 | c.27G>A p.V9= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV61084081; called by muse, mutect2, varscan2
- BANK1 | c.1542G>A p.P514= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs199703882, COSV59840070; called by muse, mutect2
- GJA8 | c.264G>A p.P88= | Silent (SNP) | VAF 63/120 reads (53%) | catalogued as rs1227166611, COSV53788592; called by muse, mutect2, varscan2
- HBP1 | c.822C>T p.G274= | Silent (SNP) | VAF 73/261 reads (28%) | catalogued as rs747014538, COSV56017432; called by muse, mutect2, varscan2
- KIAA1210 | c.2616C>T p.D872= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs759485627, COSV68176681; called by muse, mutect2, varscan2
- NR2C2 | c.1467C>G p.G489= (on ENST00000393102; = p.G508= on NM_003298.5) | Silent (SNP) | VAF 71/175 reads (41%) | catalogued as COSV60145855; called by muse, mutect2, varscan2
- OR10V1 | c.598C>T p.L200= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV55697115; called by muse, mutect2, varscan2
- TMPRSS3 | c.687C>T p.P229= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs1313025141, COSV52301977, COSV52307273; called by muse, mutect2, varscan2
- USP15 | c.1344T>C p.C448= (on ENST00000280377 / NM_001351159.2; = p.C419= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 60/141 reads (43%) | catalogued as COSV54790879; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825247 A>C | 5'Flank (SNP) | VAF 56/132 reads (42%) | called by muse, mutect2
- Z82190.2 | c.1787-18124T>C | Intron (SNP) | VAF 205/458 reads (45%) | catalogued as COSV50734926; called by muse, mutect2, varscan2
- ZNF833P | n.648C>T | RNA (SNP) | VAF 43/137 reads (31%) | called by muse, mutect2, varscan2
